Surgical pathology report (de-identified scan), TCGA case TCGA-60-2725, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Roswell Park, specimen TCGA-60-2725-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REPORT

SPECIMEN(S): A. 2 R RIGHT PROXIMAL PARATRACHEAL
B. 4 R RIGHT DISTAL PARATRACHEAL
C. 4 L LEFT DISTAL PARATRACHEAL
D. LEVEL 7 LYMPH NODE
E. LEVEL 2 LYMPH NODE
F. LEVEL 1 LYMPH NODE
G. POSTERIOR PLEURAL BX
H. 10 L LYMPH NODE
I. LEFT UPPER LOBE OF LUNG WITH LARGE TUMOR
J. LEVEL 5 AND 6 LYMPH NODE PACKET
K. ADDITIONAL 6 LN
L. ADDITIONAL 5 LN
M. 11 L LYMPH NODE

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Right upper lobe mass

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSA1: 2R lymph node: No tumor seen.

FSB1: 4R lymph node: No tumor seen.

FSC1: 4L lymph node: No tumor seen.

FSD1: Level 7 lymph node: No tumor seen

FSE1: Level 2 lymph node: No tumor seen

FSF1: Level 1 lymph node: No tumor seen

By Dr. [REDACTED] called to Dr. [REDACTED] at 12:07 p.m. (A,B), 12:12 p.m. (C), 12:25 p.m. (D, E, F)

FSG-posterior pleural biopsy: No tumor seen called [REDACTED]

[page 2 of 5]
[REDACTED]

FSI1: Left upper lobe of lung: Bronchial margin: No tumor seen.

[REDACTED]

GROSS DESCRIPTION:

A. 2 R RIGHT PROXIMAL PARATRACHEAL

Received fresh labeled with the patients identification and "2R LN" are multiple fragments of tan-pink to black tissue aggregating 0.7 x 0.5 x 0.3 cm. The specimen is entirely sent for frozen section and permanents in block A1.

B. 4R RIGHT DISTAL PARATRACHEAL

Received fresh labeled with the patients identification and "4R LN" are 3 irregular tan-pink to black fragments aggregating 0.6 to 0.5 x 0.3 cm. The specimen is entirely submitted for frozen section and permanents in block B1.

C. 4L LEFT DISTAL PARATRACHEAL

Received fresh labeled with the patients identification and "4L LN" are 3 irregular tan-pink to black tissue fragments aggregating 0.4 x 0.3 x 0.2 cm. The specimen is entirely submitted for frozen section and permanents in block C1.

D. LEVEL 7 LYMPH NODE

Received fresh labeled with the patients identification and "level 7 LN" are multiple irregular tan-pink to black tissue fragments which are entirely submitted for frozen section and permanents in block D1.

E. LEVEL 2 LYMPH NODE

Received fresh labeled with the patients identification and "2L LN" are multiple tan-pink to black tissue fragments aggregating 0.3 x 0.4 x 0.2 cm which are entirely sent for frozen section and permanents in cassette E1.

F. LEVEL 1 LYMPH NODE

Received fresh labeled with the patients identification and "level 1 LN" is a 1.5 x 0.7 x 0.3 cm lymph node, which is entirely submitted for frozen section and permanents in cassette F1.

[REDACTED]

G. POSTERIOR PLEURAL BIOPSY

Received fresh is a fragment of soft tissue, 1.1 x 1.1 x 0.3 cm. Submitted entirely frozen section diagnosis in cassette FSG.

[REDACTED]

H. 10 L LYMPH NODE

Received in formalin in a container labeled with the patient's identification and designated "10 L lymph node" is a gray-red fragment of lymphoid tissue measuring 1.5 x 0.5 x 0.4 cm. The entire specimen is submitted in cassette H1.

I. LEFT UPPER LOBE OF LUNG WITH LARGE TUMOR

Received fresh labeled "left upper lobe of lung with large tumor" is a lobectomy specimen measuring 19 x 13.5 x 4.0 cm in greatest dimension. The pleural surface has previously been focally incised. The bronchial surgical margin is submitted for frozen section. Upon sectioning the lung, there is a peripheral large tumor mass, measuring 5.0 x 4.5 x 4.0 cm in greatest dimension. This mass is tan-gray, with a whitish periphery. The central aspect of this tumor mass is necrotic. Portions of this tumor have been procured. The tumor mass grossly appears to extend to the visceral pleura. The mass extends to within 1 cm of the bronchial surgical margin.

[page 3 of 5]
[REDACTED]

The mass also closely abuts some bronchial vessels. Several lymph nodes are recovered from the peri-hilar area; all appear grossly negative for tumor. Summary of sections:

I1: frozen section tissue

I2-I8: representative tumor with overlying pleura.

I9-I10: representative tumor with adjacent peribronchial vessels

I11-I12: representative uninvolved lung parenchyma

I13-I17: each with one peri-hilar lymph node, bisected

I18: one peri-hilar lymph node, trisected

I19: additional peri-hilar lymph nodes

[REDACTED]

J. LEVEL 5 AND 6 LYMPH NODE PACKET

Received in formalin in a container labeled with the patient's identification and designated "level 5 and 6 lymph node packet" are multiple fragments of gray-red soft tissue measuring 2.6 x 1.5 x 0.3 cm in aggregate. The entire specimen is submitted in cassette J1.

K. ADDITIONAL 6 LYMPH NODE

Received in formalin in a container labeled with the patient's identification and designated "additional 6 lymph node" is a fragment of adipose tissue measuring 1.5 x 0.9 x 0.3 cm. The entire specimen is submitted K1.

L. ADDITIONAL 5 LYMPH NODE

received in formalin in a container labeled with the patient's identification and designated "additional 5 lymph node" and a fragment of red-tan lymphoid tissue measuring 1.1 x 0.5 x 0.3 cm. The entire specimen is submitted in cassette L1.

M. 11L LYMPH NODE

received in formalin in a container labeled with the patient's identification and designated "11 L lymph node" is a fragment of red-tan soft tissue measuring 1.2 x 0.6 x 0.3 cm. The entire specimen is submitted in cassette M1.

[REDACTED]

DIAGNOSIS:

A. LYMPH NODE, PROXIMAL PARATRACHEAL, 2R, BIOPSY:

- ANTHRACOTIC LYMPH NODE, NEGATIVE FOR METASTASES (0/1).

B. LYMPH NODE, DISTAL PARATRACHEAL, 4R, BIOPSY:

- ANTHRACOTIC LYMPH NODE, NEGATIVE FOR METASTASES (0/1).

C. LYMPH NODE, DISTAL PARATRACHEAL, 4L, BIOPSY:

- ANTHRACOTIC LYMPH NODE, NEGATIVE FOR METASTASES (0/1).

D. LYMPH NODE, LEVEL 7, BIOPSY:

- ANTHRACOTIC LYMPH NODE, NEGATIVE FOR METASTASES (0/1).

E. LYMPH NODE, LEVEL 2, BIOPSY:

- ANTHRACOTIC LYMPH NODE, NEGATIVE FOR METASTASES (0/1).

[page 4 of 5]
F. LYMPH NODE, LEVEL 1, BIOPSY:

- ANTHRACOTIC LYMPH NODE, NEGATIVE FOR METASTASES (0/1).

G. PLEURA, POSTERIOR, BIOPSY:

- PLEURA WITH FIBROSIS, NO TUMOR SEEN.

H. LYMPH NODE, 10 L, BIOPSY:

- ANTHRACOTIC LYMPH NODE, NEGATIVE FOR METASTASES (0/1).

I. LUNG, LEFT UPPER LOBE, LOBECTOMY:

- MODERATELY TO POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA WITH NECROSIS, MEASURING 5.0-CM
- BRONCHIAL MARGIN NEGATIVE FOR TUMOR
- NINE LYMPH NODES, NEGATIVE FOR METASTASES (0/9)
- SEE SYNOPTIC REPORT.

J. LYMPH NODE, LEVELS 5 AND 6, BIOPSY:

- ANTHRACOTIC LYMPH NODE, NEGATIVE FOR METASTASES (0/1).

K. LYMPH NODE, ADDITIONAL 6, BIOPSY:

- ANTHRACOTIC LYMPH NODE, NEGATIVE FOR METASTASES (0/1).

L. LYMPH NODE, ADDITIONAL 5, BIOPSY:

- ANTHRACOTIC LYMPH NODE, NEGATIVE FOR METASTASES (0/1).

M. LYMPH NODE, 11L, BIOPSY:

- ANTHRACOTIC LYMPH NODE, NEGATIVE FOR METASTASES (0/1).

SYNOPTIC REPORT - LUNG

Surgical Procedure: Lobectomy

Laterality: Left

Tumor Site: Upper lobe

Tumor Location: Central

Tumor Size: Greatest diameter: 5cm

WHO CLASSIFICATION

Squamous cell carcinoma

Conventional type 8070/3

Histologic Grade: G3: Poorly differentiated

Angiolymphatic Invasion: Absent

Bronchial Margins: Bronchial margins uninvolved

Visceral Pleural Involvement: Absent

[page 5 of 5]
Satellite Tumor(s): Absent

Lymph Node Involvement: N1: Ipsilateral Hilar and/or Peribronchial (levels 10-14)
Negative 0 / 11
N2: Ipsilateral Mediastinal and/or Subcarinal (Levels 1-9)
Negative 0 / 7
N3: Contralateral Mediastinal/Hilar, Scalene or Supraclavicular
Negative 0 / 2

Additional Pathologic Findings: mild emphysema

Pathological Staging (pTNM): pT 2 N 0 M x

Source: NCI Genomic Data Commons file d085de0f-e921-4e7e-ac66-98a2d5c4e0f2 (TCGA-60-2725.86E5A074-BB1A-426E-987D-FC91FFD0EF21.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).